Somatic mutation profile of tumor specimen TCGA-WE-A8K4-01A (aliquot TCGA-WE-A8K4-01A-12D-A372-08) from TCGA case TCGA-WE-A8K4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 85.7 years (31,308 days).
Specimen TCGA-WE-A8K4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b2bc8d2-ed77-49ad-b67e-757854136290.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WE-A8K4-10A (Blood Derived Normal), aliquot TCGA-WE-A8K4-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c1a21b6-d7ae-4697-aa60-6ccfa54c529c

The open-access MAF lists 1,031 somatic variants for this specimen: 657 protein-altering or splice-affecting, 350 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 586, Silent 350, Nonsense Mutation 45, Splice Region 15, Intron 13, RNA 8, Frame Shift Del 6, Splice Site 4, 3'UTR 2, 5'Flank 1, In Frame Ins 1.

Variants (750 of 1,031; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DES | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as rs62635763, CM072982, COSV100900438; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MARCHF10 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs17853369, COSV60886636; called by muse, mutect2, varscan2
- PTPRT | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61963254; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, mutect2
- SYT13 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs868559206, COSV50072436, COSV50073637; called by muse, mutect2, varscan2
- ABCB10 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100747978; called by muse, mutect2, varscan2
- ABLIM2 | c.1448C>T p.S483F (on ENST00000341937 / NM_001130084.2; = p.S432F on NM_032432.5) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV56405810; called by muse, mutect2, varscan2
- AC006059.2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1213951987, COSV100045592; called by muse, mutect2, varscan2
- AC018630.4 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as COSV99958526; called by muse, mutect2, varscan2
- ACSM2A | c.1409G>A p.G470E (on ENST00000219054; = p.G391E on NM_001308169.2) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99525313; called by mutect2, varscan2
- ACSM2B | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100312739; called by muse, mutect2, varscan2
- ACTG2 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); catalogued as COSV100609234; called by muse, mutect2, varscan2
- ACTL6A | c.784T>A p.F262I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101199680; called by muse, mutect2, varscan2
- ADAM2 | c.2138G>A p.R713K | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.232); catalogued as rs1317686368, COSV99697408; called by muse, mutect2, varscan2
- ADAM22 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99717152; called by muse, mutect2, varscan2
- ADAM9 | c.2297T>C p.V766A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs548056219, COSV101166133; called by mutect2, varscan2
- ADARB2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67235567; called by muse, mutect2, varscan2
- ADGRL3 | c.3137C>T p.S1046L (on ENST00000506720 / NM_001322402.2; = p.S978L on NM_015236.6) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101547203; called by muse, mutect2, varscan2
- ADGRV1 | c.8054T>C p.L2685S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101316078; called by muse, mutect2, varscan2
- ADH1C | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs569012082, COSV101565169; called by muse, mutect2, varscan2
- ADH4 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99644214; called by muse, mutect2, varscan2
- ADM | c.30C>A p.Y10* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV99534252; called by muse, mutect2, varscan2
- AGRN | c.5200C>T p.R1734C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372565629, COSV65068404; ClinVar: uncertain significance; called by muse, mutect2
- AGTR1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100837066; called by muse, mutect2, varscan2
- AGTR1 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100837067; called by muse, mutect2, varscan2
- AIM2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100931084; called by muse, mutect2, varscan2
- AK9 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as rs775583178, COSV53423700, COSV99572572; called by muse, mutect2
- AL645922.1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.078); catalogued as rs139113913, COSV54963040; called by muse, mutect2, varscan2
- ALK | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1263523427, COSV101202101; called by muse, mutect2, varscan2
- ALMS1 | c.8419C>T p.Q2807* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as rs1314753569, COSV100042651; called by muse, mutect2, varscan2
- ALOX15B | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV101205625; called by muse, mutect2, varscan2
- ALOXE3 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.949); catalogued as COSV59073850, COSV59077922; called by muse, mutect2
- ALPK2 | c.3857C>T p.P1286L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV100864448; called by muse, mutect2, varscan2
- ALPK3 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as COSV99361053; called by muse, mutect2, varscan2
- AMER3 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV58467681; called by muse, mutect2, varscan2
- ANKAR | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV99854329; called by muse, mutect2, varscan2
- ANKRD45 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs779907966, COSV100322525, COSV60962770; called by muse, mutect2, varscan2
- ANP32D | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV99874327; called by muse, mutect2, varscan2
- AP4B1 | c.1343A>C p.E448A | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV56725404, COSV99870831; called by muse, mutect2, varscan2
- APBA2 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101382273; called by muse, mutect2, varscan2
- API5 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); catalogued as COSV101124546; called by muse, mutect2, varscan2
- APOB | c.3055A>G p.T1019A | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV51937298, COSV99265943; called by muse, mutect2, varscan2
- ARAP2 | c.1334C>G p.S445C | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100394745; called by muse, mutect2, varscan2
- ARFGAP3 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV54312196; called by muse, mutect2, varscan2
- ARFGEF3 | c.4836A>C p.Q1612H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as COSV99293739; called by muse, mutect2, varscan2
- ARHGAP11A | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755147180, COSV100853260; called by muse, mutect2, varscan2
- ARHGAP33 | c.2834C>T p.P945L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV50123001; called by muse, mutect2, varscan2
- ARHGAP4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100604076, COSV63131780; called by muse, mutect2, varscan2
- ARHGEF12 | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1230537338, COSV100754963; called by muse, mutect2, varscan2
- ARHGEF5 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs578046612, COSV99282873; called by muse, mutect2, varscan2
- ARID1A | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61377000; called by muse, mutect2, varscan2
- ARID4B | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775501473, COSV99935722; called by muse, mutect2, varscan2
- ARSL | c.1040T>A p.L347H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101140588; called by muse, mutect2, varscan2
- ASIC2 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as COSV100726516; called by muse, varscan2
- ASXL3 | c.2797C>T p.R933W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs376307971; called by muse, mutect2, varscan2
- ATF7IP2 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV61094801; called by muse, mutect2, varscan2
- ATG2B | c.5129A>T p.N1710I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99952087; called by muse, mutect2, varscan2
- ATMIN | c.2054C>T p.S685F | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.216); catalogued as COSV100214638; called by muse, mutect2, varscan2
- ATP1A4 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as rs768634735, COSV100927568; called by muse, mutect2, varscan2
- ATP1B3 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs762081078, COSV99657313; called by muse, mutect2, varscan2
- ATP8A1 | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs1468128450, COSV100046386, COSV100047564; called by muse, mutect2, varscan2
- AUTS2 | c.1690T>C p.F564L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100717566; called by muse, mutect2, varscan2
- AXDND1 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.055); catalogued as rs772723024, COSV100858277, COSV100858455; called by muse, mutect2, varscan2
- BBS9 | c.1332C>T p.V444= | Splice Region (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99628532; called by muse, mutect2, varscan2
- BCAN | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.815); catalogued as COSV100228164; called by muse, mutect2
- BCL11A | c.1190C>T p.S397L (on ENST00000335712 / NM_001365609.1; = p.S431L on NM_018014.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs138166869, COSV59625097; called by muse, mutect2, varscan2
- BICRAL | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs143045076; called by muse, mutect2, varscan2
- BIRC6 | c.8311C>T p.P2771S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs761264901, COSV101428350; called by muse, mutect2, varscan2
- BNC2 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66155565; called by muse, mutect2, varscan2
- BOC | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs200052465, COSV99848814; called by muse, mutect2, varscan2
- BPI | c.1300G>A p.D434N (on ENST00000262865; = p.D430N on NM_001725.3) | Missense Mutation (SNP) | VAF 142/310 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1479665815, COSV99480698; called by muse, mutect2, varscan2
- BRAP | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV100554166; called by muse, mutect2, varscan2
- BRINP1 | c.1784G>A p.S595N | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV56313751; called by muse, mutect2, varscan2
- BRINP2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.142); catalogued as COSV64175547; called by muse, mutect2, varscan2
- BTBD2 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775145768, COSV99724786; called by muse, varscan2
- BTNL8 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV99180444, COSV99180473; called by muse, mutect2, varscan2
- C1QC | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs755489439, COSV101009480; called by muse, mutect2, varscan2
- C1orf109 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100523646; called by muse, mutect2, varscan2
- C3 | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs781541367, COSV55569106; called by muse, mutect2, varscan2
- C4orf51 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.173); catalogued as rs190890929, COSV101440000; called by muse, mutect2, varscan2
- C6orf201 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs1266312987, COSV100326522, COSV100326712; called by muse, mutect2, varscan2
- CA5A | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as rs747262976, COSV59241572; called by muse, mutect2, varscan2
- CACNA1E | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1251561361, COSV62439633; called by muse, mutect2
- CACNA1E | c.2714T>C p.V905A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100702991; called by muse, mutect2, varscan2
- CAGE1 | c.880G>A p.E294K (on ENST00000512086; = p.E158K on NM_205864.3) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV99699765; called by muse, mutect2, varscan2
- CAPN13 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as COSV54431064; called by muse, mutect2, varscan2
- CASR | c.1576A>T p.I526F (on ENST00000490131; = p.I603F on NM_000388.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV99949031; called by muse, mutect2
- CATSPERD | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs745670557, COSV58465097; called by muse, mutect2, varscan2
- CCDC14 | c.1039G>A p.E347K (on ENST00000488653; = p.E299K on NM_022757.5) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV100113250; called by muse, mutect2, varscan2
- CCDC141 | c.3060G>A p.E1020= | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as rs758902266, COSV99836894; called by muse, mutect2, varscan2
- CCDC158 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101187265; called by muse, mutect2, varscan2
- CCDC183 | c.477G>T p.M159I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs1262524034, COSV100566030; called by muse, mutect2, varscan2
- CCDC190 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100905831, COSV63363079; called by muse, mutect2, varscan2
- CCDC198 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99371267; called by muse, mutect2, varscan2
- CCDC33 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV99166025; called by muse, mutect2, varscan2
- CCDC42 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs374455661; called by muse, mutect2, varscan2
- CCDC62 | c.1654G>A p.G552R | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as rs1263719641, COSV99457241; called by muse, mutect2, varscan2
- CCDC71 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100422368; called by muse, mutect2, varscan2
- CCDC88C | c.4524G>A p.M1508I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV57797303; called by muse, mutect2, varscan2
- CCR2 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 49/203 reads (24%) | catalogued as COSV99432425; called by muse, mutect2, varscan2
- CCR3 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100656556; called by muse, mutect2, varscan2
- CD1A | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV56860318, COSV99192402; called by muse, mutect2, varscan2
- CD1C | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs746301692, COSV100939403, COSV63807353; called by muse, mutect2, varscan2
- CD33 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as COSV99220502; called by muse, mutect2, varscan2
- CD3G | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1202216945, COSV99416719; called by muse, mutect2, varscan2
- CD48 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.809); catalogued as COSV100924239; called by muse, mutect2, varscan2
- CD93 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs757350790, COSV99849270; called by muse, mutect2, varscan2
- CDH6 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99419436; called by muse, mutect2, varscan2
- CDK18 | c.883G>A p.D295N (on ENST00000506784 / NM_212503.3; = p.D265N on NM_002596.4) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs980809703, COSV100774039; called by muse, mutect2, varscan2
- CDRT1 | c.1380C>A p.F460L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.388); catalogued as COSV99887620; called by mutect2, varscan2
- CEACAM18 | c.672C>T p.A224= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101140418; called by muse, mutect2, varscan2
- CELA3B | c.486G>A p.W162* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as rs543692001, COSV61404657, COSV99055974; called by muse, mutect2, varscan2
- CEMIP | c.3734G>A p.G1245D | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99586820; called by muse, mutect2, varscan2
- CEP135 | c.2764C>T p.R922* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as rs369943972; called by muse, mutect2
- CEP250 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150110885; called by muse, mutect2, varscan2
- CERS4 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99250650; called by muse, mutect2, varscan2
- CETN2 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64743511; called by muse, mutect2, varscan2
- CFAP54 | c.5966G>T p.G1989V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100733203; called by muse, mutect2, varscan2
- CFTR | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as CM983544, COSV99136725; called by muse, mutect2, varscan2
- CH25H | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1380052356, COSV100897325, COSV100897402; called by muse, mutect2, varscan2
- CIBAR2 | c.426C>T p.I142= | Splice Region (SNP) | VAF 27/80 reads (34%) | catalogued as rs747509166, COSV101608280; called by muse, mutect2, varscan2
- CIBAR2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101608281; called by muse, mutect2, varscan2
- CNTN2 | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs758929116, COSV100085108; called by muse, mutect2, varscan2
- CNTN5 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99677698; called by muse, mutect2, varscan2
- CNTNAP1 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV52851808; called by muse, mutect2, varscan2
- COL1A1 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1211671, COSV99867366; called by muse, mutect2, varscan2
- COL21A1 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778906; called by muse, mutect2, varscan2
- COL4A4 | c.3546G>T p.L1182F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100306985; called by muse, mutect2, varscan2
- COL6A5 | c.6259G>A p.A2087T (on ENST00000312481; = p.A2083T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as rs1364724193, COSV99593404; called by muse, mutect2, varscan2
- COL9A1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs780899445, COSV61831236; called by muse, mutect2, varscan2
- COPS3 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99253697; called by muse, mutect2, varscan2
- CORIN | c.2090A>G p.N697S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99903754; called by muse, mutect2, varscan2
- CPED1 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV100120865; called by muse, mutect2, varscan2
- CR2 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100889655, COSV65509043; called by muse, mutect2, varscan2
- CSMD1 | c.2026C>T p.Q676* (on ENST00000520002; = p.Q675* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs1287947266, COSV100148827; called by muse, mutect2, varscan2
- CSMD2 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs142435887, COSV53892310; called by muse, mutect2, varscan2
- CTAGE1 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.17); catalogued as COSV66945357; called by muse, mutect2, varscan2
- CTNNA2 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV63582553; called by muse, mutect2, varscan2
- CTSD | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99362416; called by muse, mutect2, varscan2
- CXorf21 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100973289; called by muse, mutect2, varscan2
- CYP11A1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs746351603, COSV51430535, COSV51434240; called by muse, mutect2, varscan2
- CYP2C19 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV64909429; called by muse, mutect2, varscan2
- CYP4V2 | c.987G>C p.E329D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV101114894; called by muse, mutect2, varscan2
- DAB1 | c.1532C>T p.S511L (on ENST00000371231; = p.S478L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs530254461, COSV100976385; called by muse, mutect2, varscan2
- DCAF4 | c.908-1G>A p.X303_splice | Splice Site (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100611051; called by muse, mutect2, varscan2
- DCC | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100500517; called by muse, varscan2
- DICER1 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100602163; called by muse, mutect2, varscan2
- DISP2 | c.899G>A p.W300* | Nonsense Mutation (SNP) | VAF 32/138 reads (23%) | catalogued as COSV99140067; called by muse, mutect2, varscan2
- DIXDC1 | c.654C>T p.S218= | Splice Region (SNP) | VAF 3/11 reads (27%) | catalogued as rs782551984, COSV100180265; called by muse, mutect2
- DLG3 | c.922A>C p.K308Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99529632; called by muse, mutect2, varscan2
- DMXL1 | c.7615C>T p.R2539* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as COSV60708259; called by muse, mutect2
- DNAH1 | c.4522C>T p.Q1508* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as rs1321798402, COSV101326001; called by muse, mutect2, varscan2
- DNAH17 | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs763243487, COSV67756875; called by muse, mutect2, varscan2
- DNAH5 | c.8882G>A p.G2961E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54256658; called by muse, mutect2, varscan2
- DNAH7 | c.9988G>A p.E3330K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100414812; called by muse, mutect2, varscan2
- DNAH7 | c.4797G>A p.M1599I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs1232179847, COSV56760098; called by muse, mutect2, varscan2
- DNAH9 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs1443985595, COSV52335653; called by muse, mutect2, varscan2
- DPYD | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64604804; called by muse, mutect2, varscan2
- DRD5 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100431811; called by muse, mutect2, varscan2
- DRGX | c.234G>A p.Q78= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100938349; called by muse, mutect2, varscan2
- DROSHA | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as rs200373457; called by muse, mutect2, varscan2
- DROSHA | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100757640; called by muse, mutect2, varscan2
- DSC3 | c.1733T>A p.L578H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100844611; called by muse, mutect2, varscan2
- DSCAM | c.4748A>C p.N1583T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101260361; called by muse, mutect2, varscan2
- DUSP15 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1356563282, COSV99639830; called by muse, mutect2, varscan2
- DUSP21 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV100173590; called by muse, mutect2, varscan2
- DYDC2 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs1281417710, COSV99758103; called by muse, mutect2, varscan2
- DYNC2H1 | c.11315G>A p.R3772H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs371973761, COSV62107307; called by muse, mutect2, varscan2
- EDAR | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as COSV99303731; called by muse, mutect2
- EFNA4 | c.115T>C p.L39= | Splice Region (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99665036; called by muse, mutect2
- EGR4 | c.1193G>A p.G398E (on ENST00000545030; = p.G295E on NM_001965.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.431); catalogued as rs767303471, COSV101474252; called by muse, mutect2, varscan2
- EIF3A | c.2926A>G p.R976G | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100974640; called by muse, mutect2, varscan2
- ENAH | c.1645C>T p.Q549* (on ENST00000366844 / NM_001008493.3; = p.Q528* on NM_018212.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV99490807; called by muse, mutect2, varscan2
- ENTPD3 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100088743, COSV57195569; called by muse, mutect2, varscan2
- ENTPD4 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV100652666; called by muse, mutect2
- EP400 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV100201339; called by muse, mutect2, varscan2
- ERBB4 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.944); catalogued as rs377737065; called by muse, mutect2, varscan2
- ERBB4 | c.3239C>T p.P1080L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100726100; called by muse, mutect2, varscan2
- ERG | c.938C>T p.P313L (on ENST00000398919 / NM_001243428.1; = p.P289L on NM_004449.4) | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99902033; called by muse, mutect2, varscan2
- ERICH3 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs764527597, COSV58605360, COSV58606466; called by muse, mutect2, varscan2
- ETAA1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99712799; called by muse, mutect2, varscan2
- ETV5 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.138); catalogued as COSV100112344; called by muse, mutect2, varscan2
- EYA2 | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs775507043, COSV100426931; called by muse, mutect2, varscan2
- F13A1 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99343169; called by muse, mutect2, varscan2
- F5 | c.4201C>T p.P1401S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.005); catalogued as COSV100889127; called by muse, mutect2, varscan2
- FAM135B | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs867284054, COSV52749527; called by muse, mutect2, varscan2
- FAM166A | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs555243390, COSV61119462; called by muse, mutect2, varscan2
- FAM171A1 | c.2558G>A p.R853K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs760976201, COSV100968293; called by muse, mutect2, varscan2
- FAM71A | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99674653; called by muse, mutect2, varscan2
- FAT3 | c.7687C>T p.P2563S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.279); catalogued as COSV99966827; called by muse, mutect2, varscan2
- FAT4 | c.6035C>T p.S2012F | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100628823; called by muse, mutect2, varscan2
- FAT4 | c.7963G>A p.E2655K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.993); catalogued as rs556536853, COSV58679417; called by muse, mutect2, varscan2
- FBXO43 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV101413862, COSV71055522; called by muse, mutect2, varscan2
- FCN3 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs376437282; called by muse, mutect2, varscan2
- FGD5 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99548216; called by muse, mutect2, varscan2
- FLG2 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV66170591, COSV66173164; called by muse, mutect2, varscan2
- FLNB | c.6819A>C p.E2273D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99913460; called by muse, mutect2, varscan2
- FLNC | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.091); catalogued as COSV100368199; called by muse, mutect2, varscan2
- FLT4 | c.3655C>T p.P1219S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1439215901, COSV99987272; called by muse, mutect2, varscan2
- FMO3 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100882459; called by muse, mutect2, varscan2
- FOSB | c.639T>A p.F213L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100798704, COSV100798775; called by muse, mutect2, varscan2
- FRG1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.944); catalogued as rs779532235, COSV99903199; called by muse, mutect2
- FRG2B | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.887); catalogued as rs1328251782; called by muse, mutect2
- FUT8 | c.859C>T p.Q287* (on ENST00000360689 / NM_001371534.1; = p.Q124* on NM_004480.4) | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100651405; called by muse, mutect2, varscan2
- GABRA2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1480056834, COSV100734110, COSV62916543; called by muse, mutect2, varscan2
- GBP5 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs138002260; called by muse, mutect2, varscan2
- GCNT2 | c.729C>A p.Y243* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV101097453; called by muse, mutect2, varscan2
- GFRAL | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs749227939, COSV61229928; called by muse, mutect2, varscan2
- GJB6 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.089); catalogued as rs571454176, CM1110302, COSV53831881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLIS3 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.414); catalogued as COSV101127555; called by muse, mutect2, varscan2
- GLRA3 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99927638; called by muse, mutect2, varscan2
- GNAI2 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV99807055; called by muse, mutect2
- GNL2 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs757597500, COSV66079634; called by muse, mutect2, varscan2
- GOLM1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as COSV99974387; called by muse, mutect2, varscan2
- GPR158 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350723305, COSV66274209; called by muse, mutect2, varscan2
- GPR22 | c.1215G>A p.W405* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs755787034, COSV99772293; called by muse, mutect2, varscan2
- GPRC5C | c.415C>T p.L139F (on ENST00000652232; = p.L94F on NM_018653.4) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1269581247, COSV100702906; called by muse, mutect2, varscan2
- GRHL1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100257866; called by muse, mutect2
- GRID1 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1247733826, COSV100024363; called by muse, mutect2, varscan2
- GRM6 | c.2462C>T p.T821I | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs766938162, COSV99179646; called by muse, mutect2, varscan2
- GRM7 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as rs1370360489, COSV100736868; called by muse, mutect2, varscan2
- GUCY2C | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as COSV99663729; called by muse, mutect2, varscan2
- HAL | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs367677601; called by muse, mutect2, varscan2
- HCN1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV57495742; called by muse, mutect2, varscan2
- HCN1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57517620; called by muse, mutect2, varscan2
- HECTD1 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237407; called by muse, mutect2, varscan2
- HECTD1 | c.3655G>T p.G1219W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101237408; called by muse, mutect2, varscan2
- HEPHL1 | c.3016C>T p.H1006Y | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100244003; called by muse, mutect2, varscan2
- HHATL | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs776663186, COSV100124480; called by muse, mutect2, varscan2
- HHLA2 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV63315189; called by muse, mutect2, varscan2
- HIP1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100417604; called by muse, mutect2, varscan2
- HIVEP2 | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99173686; called by muse, mutect2, varscan2
- HLA-DRA | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs867285682, COSV66622958; called by muse, mutect2, varscan2
- HMCN1 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99630102; called by muse, mutect2, varscan2
- HNF4G | c.121C>T p.R41C (on ENST00000354370 / NM_001330561.2; = p.R88C on NM_004133.5) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62966093; called by muse, mutect2, varscan2
- HSPA13 | c.98T>G p.V33G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99580084; called by muse, mutect2, varscan2
- HSPG2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.953); catalogued as COSV65930240; called by muse, mutect2, varscan2
- HTR1E | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100541127; called by muse, mutect2, varscan2
- HTR2C | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52204349, COSV99349599; called by muse, mutect2, varscan2
- HTRA4 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56759834; called by muse, mutect2, varscan2
- HYDIN | c.1819G>A p.G607S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99863430; called by muse, mutect2, varscan2
- IDO1 | c.368T>G p.I123S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99503376; called by muse, mutect2, varscan2
- IFNA8 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.715); catalogued as COSV101206909; called by muse, mutect2, varscan2
- IGSF1 | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs775890919, COSV100812119; called by muse, mutect2, varscan2
- IL18RAP | c.396G>A p.K132= | Splice Region (SNP) | VAF 12/82 reads (15%) | catalogued as rs1391757960, COSV51827259; called by muse, mutect2, varscan2
- IL1RL1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.927); catalogued as rs368053458; called by muse, mutect2, varscan2
- IL21R | c.796A>T p.K266* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100560166; called by muse, mutect2
- INAVA | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs1226162337, COSV66256294; called by muse, mutect2, varscan2
- INSR | c.4142C>T p.P1381L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV57158492; called by muse, mutect2, varscan2
- INSYN1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as rs1482749606, COSV101138789; called by muse, mutect2, varscan2
- IQGAP2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57168953; called by muse, mutect2, varscan2
- IQGAP3 | c.1762T>A p.W588R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100752170; called by muse, mutect2, varscan2
- ITPR1 | c.1884C>T p.P628= (on ENST00000354582; = p.P613= on NM_002222.7) | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100231562; called by muse, mutect2, varscan2
- JADE3 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1355562695, COSV99509937; called by muse, mutect2, varscan2
- JMY | c.2575T>A p.S859T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1477202074, COSV101268032; called by muse, mutect2, varscan2
- KALRN | c.3716G>A p.G1239E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99564910; called by muse, mutect2, varscan2
- KASH5 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs762241865, COSV71358094; called by muse, mutect2, varscan2
- KCNA6 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.017); catalogued as rs374946304, COSV99768688; called by muse, mutect2, varscan2
- KCNA6 | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.068); catalogued as COSV99768689; called by muse, mutect2, varscan2
- KCNH3 | c.2466C>T p.P822= | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99235298; called by muse, mutect2, varscan2
- KCNH5 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.229); catalogued as rs144667189, COSV59781173; called by muse, mutect2, varscan2
- KCNV1 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV99819152; called by muse, mutect2, varscan2
- KIAA1549 | c.3008C>T p.S1003F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1195528738, COSV54328807; called by muse, mutect2, varscan2
- KIF12 | c.1318G>A p.E440K (on ENST00000640217; = p.E302K on NM_138424.1) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV100936165; called by muse, mutect2
- KIF18A | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99588771; called by muse, mutect2, varscan2
- KIFC2 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023835; called by muse, mutect2, varscan2
- KLHL1 | c.208A>G p.K70E | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.041); catalogued as COSV100917420; called by muse, mutect2, varscan2
- KLHL22 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1205647733, COSV61021670; called by muse, mutect2, varscan2
- KLHL8 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.306); catalogued as COSV99911408; called by muse, varscan2
- KMT2B | c.3307C>T p.P1103S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1197235035, COSV55869623; called by muse, mutect2, varscan2
- KNL1 | c.1051C>T p.H351Y (on ENST00000346991 / NM_170589.5; = p.H325Y on NM_144508.5) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs1456937486, COSV100706572; called by muse, mutect2, varscan2
- KREMEN2 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1011911801, COSV99566937; called by muse, mutect2, varscan2
- KRT37 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs142829376; called by muse, mutect2, varscan2
- KRTAP10-4 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100553966; called by muse, varscan2
- KRTAP5-9 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as rs373209436; called by muse, mutect2, varscan2
- LAMB3 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs567822076, COSV61919681; called by muse, mutect2, varscan2
- LAMC2 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99917527; called by muse, mutect2, varscan2
- LARS2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs993142041, COSV99647844; called by muse, mutect2, varscan2
- LCE1D | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | PolyPhen probably damaging (0.991); catalogued as rs780003505, COSV100405911; called by muse, mutect2, varscan2
- LCE3D | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV100909847; called by muse, mutect2, varscan2
- LCE4A | c.26A>T p.Q9L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100140055; called by muse, mutect2, varscan2
- LEPR | c.3392G>A p.G1131E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.703); catalogued as COSV100848166, COSV100848233; called by muse, mutect2, varscan2
- LGALS9 | c.811C>T p.R271C (on ENST00000395473 / NM_009587.3; = p.R239C on NM_002308.4) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs529948704, COSV100119469; called by muse, mutect2, varscan2
- LGR5 | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1437375767, COSV57004843; called by muse, mutect2, varscan2
- LGR6 | c.1963G>C p.A655P (on ENST00000367278 / NM_001017403.1; = p.A603P on NM_021636.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1233217353, COSV55167019, COSV99707130; called by muse, mutect2, varscan2
- LHX8 | c.854G>A p.S285N | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs767042515, COSV99633861; called by muse, mutect2, varscan2
- LILRA1 | c.72G>A p.G24= | Splice Region (SNP) | VAF 20/93 reads (22%) | catalogued as rs765286954, COSV99251940; called by muse, mutect2, varscan2
- LILRA4 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs773279262, COSV52494773, COSV99393171; called by muse, mutect2, varscan2
- LINGO2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs779685785, COSV58059040; called by muse, mutect2, varscan2
- LINGO4 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as rs543163530, COSV100765011; called by muse, mutect2, varscan2
- LIPE | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs368651289, COSV54924790; called by muse, mutect2, varscan2
- LLGL2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99389878; called by muse, mutect2, varscan2
- LMOD1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV100939183; called by muse, mutect2, varscan2
- LPIN1 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99877674; called by muse, mutect2, varscan2
- LRP1B | c.12523C>T p.P4175S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101257724; called by muse, mutect2, varscan2
- LRP1B | c.12437G>A p.G4146D | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as COSV101257725; called by muse, mutect2, varscan2
- LRP1B | c.9524G>A p.R3175K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV101257726; called by muse, mutect2, varscan2
- LRP2 | c.6724G>A p.D2242N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788749; called by muse, mutect2, varscan2
- LRP2 | c.4987C>T p.R1663C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs898681788, COSV55553067, COSV99787664; called by muse, mutect2, varscan2
- LRRC4C | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53431599, COSV99538521; called by muse, mutect2, varscan2
- LRRC7 | c.1574G>A p.R525K (on ENST00000651989 / NM_001370785.2; = p.R492K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.057); catalogued as COSV99227385; called by muse, mutect2, varscan2
- LRRC8A | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99396651; called by muse, mutect2, varscan2
- LRRN2 | c.2082G>T p.R694S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV100912880, COSV65783423; called by muse, mutect2, varscan2
- LRRN2 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV65783883; called by muse, mutect2
- LSS | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as rs760554552, COSV100710936; called by muse, mutect2, varscan2
- LYPD3 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99747064; called by muse, varscan2
- LYZL1 | c.279G>A p.W93* (on ENST00000375500; = p.W47* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs774019051, COSV100973643; called by mutect2, varscan2
- MACF1 | c.8582G>A p.R2861K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99244798; called by muse, mutect2, varscan2
- MAGEC3 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as COSV100025519; called by muse, mutect2, varscan2
- MAP6 | c.1106A>G p.K369R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV100496721; called by muse, mutect2, varscan2
- MBD5 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431188033, COSV101290109; called by muse, mutect2, varscan2
- MCM3AP | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99387039; called by muse, mutect2, varscan2
- MDGA2 | c.2741G>C p.G914A (on ENST00000399232 / NM_001113498.2; = p.G616A on NM_182830.4) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1226592054, COSV100637351; called by muse, mutect2
- MED13L | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867033906, COSV56116816; called by muse, mutect2, varscan2
- MEI1 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100300030; called by muse, mutect2, varscan2
- MEIOB | c.812T>G p.I271R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV100379831; called by muse, mutect2, varscan2
- MEPE | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100734960; called by muse, mutect2, varscan2
- METTL9 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100820574; called by muse, mutect2, varscan2
- MEX3D | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101183507; called by muse, mutect2, varscan2
- MFF | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100449341; called by muse, mutect2, varscan2
- MFSD12 | c.343T>G p.C115G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100814884; called by mutect2, varscan2
- MICAL2 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV56319799; called by muse, mutect2, varscan2
- MLXIPL | c.1945A>G p.N649D | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100515383; called by muse, mutect2, varscan2
- MNT | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV99438116; called by muse, mutect2, varscan2
- MOGAT1 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV101490097; called by muse, mutect2, varscan2
- MON2 | c.1136A>C p.K379T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99742731; called by muse, mutect2, varscan2
- MPHOSPH10 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54906413; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1563G>A p.W521* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV100186853; called by muse, mutect2, varscan2
- MRRF | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777756492, COSV99938914; called by muse, mutect2
- MSANTD1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.332); catalogued as rs754777440, COSV101433633; called by muse, mutect2, varscan2
- MTCH2 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267602907, COSV100206994; called by muse, varscan2
- MUC16 | c.33314C>T p.S11105F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs374873225; called by muse, mutect2
- MUC16 | c.30380C>T p.S10127F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.937); catalogued as COSV67466624; called by muse, mutect2, varscan2
- MUC16 | c.25634G>A p.G8545E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as rs1419513897, COSV101200085; called by muse, mutect2, varscan2
- MUC16 | c.21235C>T p.P7079S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.327); catalogued as rs267605795, COSV101200086; called by muse, mutect2, varscan2
- MUC16 | c.5425G>A p.E1809K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.801); catalogued as COSV101200088; called by muse, mutect2, varscan2
- MUC16 | c.4069G>A p.E1357K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV101200089; called by muse, mutect2, varscan2
- MUC16 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV101200090; called by muse, mutect2, varscan2
- MUSK | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV51879707; called by muse, mutect2, varscan2
- MX1 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99912679; called by muse, mutect2, varscan2
- MXRA5 | c.5948C>T p.S1983F | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277492063, COSV54239198; called by muse, mutect2, varscan2
- MYBL1 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs749526947, COSV72919122; called by muse, mutect2, varscan2
- MYH1 | c.4182-1G>A p.X1394_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99876101; called by muse, mutect2
- MYH1 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV99876103; called by muse, mutect2, varscan2
- MYH4 | c.5169G>A p.Q1723= | Splice Region (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99701428; called by muse, mutect2, varscan2
- MYO3A | c.3449G>A p.R1150K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56327080, COSV99779979; called by muse, mutect2, varscan2
- MYO3B | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100510467; called by muse, mutect2, varscan2
- MYO7B | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.037); catalogued as rs758340636, COSV101268215, COSV101268317; called by muse, mutect2, varscan2
- MYRF | c.233C>T p.P78L (on ENST00000278836 / NM_001127392.3; = p.P69L on NM_013279.4) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs1270666186, COSV99607180; called by muse, mutect2, varscan2
- MYRIP | c.1496A>G p.N499S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100219315; called by muse, mutect2, varscan2
- NAT10 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs756436278, COSV99139892; called by muse, varscan2
- NAV2 | c.6334A>G p.T2112A (on ENST00000396087 / NM_001244963.2; = p.T2053A on NM_145117.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1329606273, COSV100217051; called by muse, mutect2
- NAV2 | c.6335C>T p.T2112M (on ENST00000396087 / NM_001244963.2; = p.T2053M on NM_145117.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs751690724, CM1514117, COSV100217054; called by muse, mutect2
- NCAM2 | c.132G>A p.A44= | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as rs942523925, COSV53086652, COSV53101523; called by muse, mutect2, varscan2
- NCOA1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99946256; called by muse, mutect2, varscan2
- NDUFA4 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV100292861; called by muse, mutect2, varscan2
- NEB | c.3640G>A p.E1214K | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs764769462, COSV50885885; called by mutect2, varscan2
- NEK10 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460856661, COSV99835257; called by muse, mutect2, varscan2
- NEK10 | c.1743G>A p.Q581= | Splice Region (SNP) | VAF 8/33 reads (24%) | catalogued as rs1265985342, COSV100411934; called by muse, mutect2, varscan2
- NFATC4 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1338533217, COSV51605799; called by muse, mutect2, varscan2
- NLRP4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.197); catalogued as COSV100016410; called by muse, mutect2, varscan2
- NLRP4 | c.1554T>A p.F518L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100016412; called by muse, mutect2, varscan2
- NOBOX | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs200423745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRG3 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV64562880; called by muse, mutect2, varscan2
- NRXN3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV73586398; called by muse, mutect2, varscan2
- NSUN7 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57274521; called by muse, mutect2, varscan2
- NTN5 | c.1393C>G p.R465G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV54306408, COSV99539438; called by muse, varscan2
- NTRK1 | c.2074C>T p.R692C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761967383, COSV62323124; called by muse, mutect2, varscan2
- NXN | c.1060A>T p.K354* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100403143; called by muse, mutect2, varscan2
- NXPH1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1562474802, COSV101339715; called by muse, mutect2, varscan2
- OBSCN | c.3995C>T p.A1332V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.865); catalogued as COSV99479436; called by muse, mutect2, varscan2
- OPRPN | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.007); catalogued as COSV68192574; called by muse, mutect2, varscan2
- OR10K1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99193612; called by muse, mutect2, varscan2
- OR1E1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100491948; called by muse, mutect2, varscan2
- OR2L13 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs780331148, COSV100813772; called by muse, mutect2, varscan2
- OR2M4 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs865876352, COSV100141273; called by muse, mutect2, varscan2
- OR2W3 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs747750632, COSV100831708, COSV64457799; called by muse, mutect2, varscan2
- OR2Z1 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as rs782472476, COSV60691691; called by muse, mutect2, varscan2
- OR2Z1 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1555756873, COSV100136444; called by muse, mutect2, varscan2
- OR3A1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100041711; called by muse, mutect2, varscan2
- OR3A2 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV101375096; called by mutect2, varscan2
- OR4M1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100271246; called by muse, mutect2, varscan2
- OR56A3 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV61569206; called by muse, mutect2, varscan2
- OR5AU1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100436146; called by muse, mutect2, varscan2
- OR5C1 | c.622G>A p.G208S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs1186976839, COSV101030572; called by muse, mutect2, varscan2
- OR6B1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV101281657, COSV68769734; called by muse, mutect2, varscan2
- OR6K3 | c.439C>T p.R147C (on ENST00000368146; = p.R131C on NM_001005327.2) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs748128044, COSV63745210; called by muse, mutect2, varscan2
- OTOF | c.3613C>T p.R1205C (on ENST00000272371 / NM_194248.3; = p.R458C on NM_004802.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs747452208, COSV55499991, COSV99717869; called by muse, mutect2, varscan2
- OXGR1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.638); catalogued as rs773971892, COSV53656791; called by muse, mutect2, varscan2
- P2RX5 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745394542, COSV99835843; called by muse, mutect2
- PAPPA2 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1332734848, COSV100866826, COSV62787129; called by muse, mutect2, varscan2
- PAPPA2 | c.3299G>A p.G1100E | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100868261; called by muse, mutect2, varscan2
- PBRM1 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239654517, COSV56302177, COSV99968289; called by muse, mutect2, varscan2
- PCDH15 | c.3790A>G p.I1264V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.366); catalogued as COSV100221817; called by muse, mutect2, varscan2
- PCDH18 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV61266449; called by muse, mutect2, varscan2
- PCDH7 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100688382; called by muse, mutect2, varscan2
- PCDHA11 | c.1657T>C p.F553L | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.938); catalogued as COSV100251044; called by muse, mutect2, varscan2
- PCDHA5 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.453); catalogued as rs782270445, COSV65351910; called by muse, mutect2, varscan2
- PCDHA5 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100972330; called by muse, mutect2, varscan2
- PCDHB1 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs1554267230, COSV100128194; called by muse, mutect2, varscan2
- PCDHGA1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV65297520; called by muse, mutect2, varscan2
- PCDHGA11 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1381295469, COSV99539493; called by muse, mutect2, varscan2
- PCDHGA2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs752154051, COSV104389952, COSV99539491; called by muse, mutect2, varscan2
- PCLO | c.3772G>A p.E1258K | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); catalogued as COSV61652778; called by muse, mutect2, varscan2
- PCSK5 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1564007113, COSV65082671; called by muse, mutect2, varscan2
- PCTP | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs199577773; called by muse, mutect2, varscan2
- PDE6B | c.1512C>G p.F504L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1471418829, COSV55330331, COSV99727679; called by muse, mutect2, varscan2
- PDE6C | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65115769, COSV65117719; called by muse, mutect2, varscan2
- PDE8B | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53737355; called by muse, mutect2, varscan2
- PGBD1 | c.1840C>A p.L614I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as COSV52551292, COSV99460385; called by muse, mutect2, varscan2
- PGLYRP4 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV100668425; called by muse, mutect2, varscan2
- PHLDB1 | c.3398C>T p.S1133F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs782289067, COSV100616583; called by muse, mutect2, varscan2
- PHLDB2 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs1209433982, COSV67312460; called by muse, mutect2, varscan2
- PIDD1 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1443241357, COSV100204104, COSV100204222; called by muse, mutect2, varscan2
- PIK3R5 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99353434; called by muse, mutect2, varscan2
- PIP4P2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.078); catalogued as rs767545840, COSV99575374; called by muse, mutect2, varscan2
- PLA2G2C | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV99930312; called by muse, mutect2, varscan2
- PLAG1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV100387945; called by muse, mutect2, varscan2
- PLCL2 | c.478C>T p.H160Y (on ENST00000615277 / NM_001144382.2; = p.H34Y on NM_015184.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV101196765; called by muse, mutect2, varscan2
- PLCL2 | c.3136G>A p.E1046K (on ENST00000615277 / NM_001144382.2; = p.E920K on NM_015184.5) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV67621071; called by muse, mutect2, varscan2
- PLD5 | c.496G>A p.G166S (on ENST00000442594; = p.G104S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1225209552, COSV59162035; called by muse, mutect2, varscan2
- PLPPR3 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200639651, COSV100608761; called by muse, mutect2, varscan2
- POF1B | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs867961567, COSV99426807; called by muse, mutect2, varscan2
- POMGNT2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753736893, COSV100768090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARGC1A | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV53526292; called by muse, mutect2, varscan2
- PPFIA2 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV100333772; called by muse, mutect2, varscan2
- PPFIA2 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61054601; called by muse, mutect2, varscan2
- PPM1E | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV100376298; called by muse, mutect2, varscan2
- PPP1R3A | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52879015; called by muse, mutect2, varscan2
- PRAMEF12 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100743315; called by muse, mutect2, varscan2
- PREX2 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868582467, COSV55755180; called by muse, mutect2, varscan2
- PRKD3 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763192669, COSV52209674; called by muse, mutect2
- PRODH2 | c.271C>T p.P91S (on ENST00000301175; = p.P15S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs747780870, COSV56558381; called by muse, mutect2, varscan2
- PRSS8 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99571515; called by muse, mutect2, varscan2
- PRUNE2 | c.2830T>C p.Y944H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100944672; called by muse, mutect2, varscan2
- PSD4 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV99831182; called by muse, mutect2, varscan2
- PSG9 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs200083247; called by muse, mutect2, varscan2
- PTGS2 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100821771; called by muse, mutect2, varscan2
- PTGS2 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as COSV100821772; called by muse, mutect2, varscan2
- PTPRC | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.009); catalogued as COSV61406736; called by muse, mutect2, varscan2
- PTPRS | c.4009G>A p.D1337N | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99510908; called by muse, mutect2, varscan2
- PXYLP1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs759460254, COSV53891145; called by muse, mutect2, varscan2
- PYHIN1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV100932543, COSV100932595, COSV63732699; called by muse, mutect2, varscan2
- PZP | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV54360744, COSV99738082; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3739C>T p.Q1247* (on ENST00000330843 / NM_001002814.3; = p.Q613* on NM_025151.5) | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | catalogued as COSV99770129; called by muse, mutect2, varscan2
- RAD54L2 | c.3673C>T p.R1225* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV56577697; called by muse, mutect2, varscan2
- RAG1 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1385203770, COSV55029241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RARS1 | c.1784A>T p.H595L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99199103; called by muse, mutect2, varscan2
- RASAL2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752504099, COSV100862458, COSV62709448; called by muse, mutect2, varscan2
- RASGRF2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99429446; called by muse, mutect2, varscan2
- RASGRP2 | c.1622A>G p.K541R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.04); catalogued as COSV100818269; called by muse, mutect2
- RASSF2 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101040798; called by muse, mutect2, varscan2
- RB1CC1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104376978, COSV99210783, COSV99212317; called by muse, mutect2
- RCC2 | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100965166; called by muse, mutect2, varscan2
- RGS18 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100817802; called by muse, mutect2, varscan2
- RGS7BP | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61833475, COSV61835070; called by muse, mutect2, varscan2
- RHOA | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV101346304; called by muse, mutect2, varscan2
- RICTOR | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99705087; called by muse, mutect2, varscan2
- RNF157 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs1555651777, COSV99487050; called by muse, mutect2, varscan2
- RNF213 | c.2710C>T p.Q904* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100173534; called by muse, mutect2, varscan2
- RP1 | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55126381; called by muse, mutect2, varscan2
- RP1L1 | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66761403; called by muse, mutect2, varscan2
- RPE65 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV52018177, COSV99254017; called by muse, mutect2, varscan2
- RPRD2 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 19/155 reads (12%) | catalogued as COSV100955100; called by muse, mutect2, varscan2
- RPRD2 | c.3611C>T p.P1204L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100955101; called by muse, mutect2, varscan2
- RPS6KC1 | c.3195G>T p.M1065I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100873919; called by muse, mutect2, varscan2
- RPTOR | c.3986C>T p.S1329L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1225229302, COSV60806287; called by muse, mutect2, varscan2
- RRM2B | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99310212; called by muse, mutect2, varscan2
- RRP8 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs1353958191, COSV99601931; called by muse, mutect2, varscan2
- RTN4RL1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV100486611; called by muse, mutect2, varscan2
- RWDD2B | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV54501575; called by muse, mutect2
- RYR1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.497); catalogued as rs771058055, COSV100615111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs376243998, COSV100770737; called by muse, mutect2, varscan2
- SCARF2 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV99839322; called by muse, mutect2
- SCN10A | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101479419, COSV71862068; called by muse, mutect2, varscan2
- SCN2A | c.5255G>A p.G1752E | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99331966; called by muse, mutect2, varscan2
- SEMA3B | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553706376, COSV100312820; called by muse, mutect2, varscan2
- SENP7 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as rs1368872376, COSV100053321; called by muse, mutect2, varscan2
- SEZ6 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100253177; called by mutect2, varscan2
- SEZ6L | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs370294088; called by muse, mutect2, varscan2
- SGCZ | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1355052545, COSV101170164; called by muse, mutect2, varscan2
- SIDT1 | c.1887G>A p.W629* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1396028559, COSV99334056; called by muse, mutect2, varscan2
- SIDT1 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99334060; called by muse, mutect2, varscan2
- SLC10A2 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99808008; called by muse, mutect2, varscan2
- SLC12A1 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.248); catalogued as COSV66792757; called by muse, mutect2
- SLC13A5 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53424035; called by mutect2, varscan2
- SLC15A2 | c.1297A>T p.N433Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99815554; called by muse, mutect2, varscan2
- SLC1A2 | c.562-1G>A p.X188_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99554600; called by muse, mutect2, varscan2
- SLC22A9 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV99655065; called by muse, mutect2, varscan2
- SLC2A7 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs780152626, COSV101280792; called by muse, mutect2, varscan2
- SLC38A6 | c.1361T>G p.I454S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99959753; called by muse, mutect2, varscan2
- SLC4A4 | c.1322G>T p.R441L (on ENST00000264485 / NM_001098484.3; = p.R397L on NM_003759.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1461830749, COSV52621554, COSV52635655; called by muse, mutect2
- SLC4A4 | c.1322+1G>A p.X441_splice (on ENST00000264485 / NM_001098484.3; = p.X397_splice on NM_003759.4) | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99140365; called by muse, mutect2
- SLC52A1 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.307); catalogued as COSV99643437; called by muse, mutect2, varscan2
- SLC5A8 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs1442552728, COSV101610562, COSV73310695; called by muse, mutect2, varscan2
- SLC6A1 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99822813; called by muse, mutect2, varscan2
- SLC9C2 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV100876781; called by muse, mutect2, varscan2
- SLCO5A1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1036408724, COSV99480177; called by muse, mutect2, varscan2
- SLIT1 | c.1433G>A p.G478E | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.826); catalogued as rs1231523248, COSV99821538; called by muse, mutect2, varscan2
- SLIT1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV56587457; called by mutect2, varscan2
- SLIT2 | c.3457G>A p.G1153R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884361; called by muse, mutect2, varscan2
- SLIT3 | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs1466972276, COSV100268026; called by muse, mutect2, varscan2
- SOAT1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV100858978; called by muse, mutect2, varscan2
- SORCS2 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as rs375293868; called by muse, mutect2, varscan2
- SORCS3 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs138480176; called by muse, mutect2, varscan2
- SPANXN2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.213); catalogued as COSV100979907; called by muse, varscan2
- SPANXN3 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100980803; called by muse, mutect2, varscan2
- SPATA19 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs748936093, COSV104406994, COSV54484506; called by muse, mutect2, varscan2
- SPATA31E1 | c.1628G>A p.R543K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.794); catalogued as COSV100350556; called by muse, mutect2, varscan2
- SPDYE1 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV99323990; called by muse, mutect2, varscan2
- SPEG | c.3071G>A p.C1024Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100404690; called by muse, mutect2, varscan2
- SPHKAP | c.1332G>A p.W444* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as rs867872641, COSV100764162; called by muse, mutect2, varscan2
- SPINK5 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99806852; called by muse, mutect2, varscan2
- SPTA1 | c.3208C>T p.R1070W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs777961517, COSV63748672, COSV63752512; called by muse, mutect2, varscan2
- SPTBN5 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as rs369056575; called by muse, varscan2
- SRGAP3 | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV64530320; called by muse, mutect2, varscan2
- SRRM2 | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1197349628, COSV100070912; called by muse, mutect2, varscan2
- ST6GAL2 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | PolyPhen benign (0.418); catalogued as COSV64526348; called by muse, mutect2, varscan2
- STAB1 | c.4400C>T p.S1467F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776759905, COSV58734102; called by muse, mutect2, varscan2
- STAB2 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866315606, COSV66335628; called by muse, mutect2, varscan2
- STK4 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV65671629; called by muse, mutect2, varscan2
- STXBP5L | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as COSV99874571; called by muse, mutect2, varscan2
- SUCO | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99742932; called by muse, mutect2, varscan2
- SULT1C2 | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.117); catalogued as COSV99265097, COSV99265220; called by muse, mutect2, varscan2
- SYNE2 | c.5503C>T p.H1835Y | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59947344; called by muse, mutect2, varscan2
- SYNJ1 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV59155387; called by muse, mutect2
- SYNRG | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469187105; called by muse, mutect2, varscan2
- TACC2 | c.8506T>A p.F2836I (on ENST00000334433; = p.F914I on NM_006997.4) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99587148; called by muse, mutect2, varscan2
- TAF1L | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV99644789; called by muse, mutect2, varscan2
- TAF3 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1265692482, COSV100720198; called by muse, mutect2, varscan2
- TAFA2 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101353434; called by muse, mutect2
- TAS2R20 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV101114961; called by muse, mutect2, varscan2
- TASOR2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778847423, COSV60168878; called by muse, mutect2, varscan2
- TCF23 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs747321212, COSV99940345; called by muse, mutect2, varscan2
- TDRD10 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99427486; called by muse, mutect2, varscan2
- TDRKH | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1004423330, COSV64316048; called by muse, mutect2, varscan2
- TENM3 | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101305170; called by muse, mutect2, varscan2
- TENM3 | c.2195G>A p.G732D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101305171; called by muse, mutect2, varscan2
- TENM3 | c.3565G>A p.G1189S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757680192, COSV101305173, COSV69315589; called by muse, mutect2, varscan2
- TESPA1 | c.1264G>A p.E422K (on ENST00000316577 / NM_001098815.3; = p.E284K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.127); catalogued as COSV57257223; called by muse, mutect2, varscan2
- TEX101 | c.583T>C p.S195P (on ENST00000598265 / NM_001130011.3; = p.S213P on NM_031451.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs748621908, COSV99494844; called by muse, mutect2, varscan2
- TF | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 30/164 reads (18%) | catalogued as COSV53917586; called by muse, mutect2, varscan2
- TG | c.4171G>A p.V1391M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99601182; called by muse, mutect2
- TGFBI | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs774850509, COSV100526526; called by muse, mutect2, varscan2
- TGFBR3 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99283121; called by muse, mutect2, varscan2
- THAP9 | c.1487T>C p.L496S | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100155875; called by muse, mutect2, varscan2
- THSD7B | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.892); catalogued as rs1250652530, COSV55712646; called by muse, mutect2, varscan2
- THSD7B | c.4670A>C p.K1557T (on ENST00000272643; = p.K1555T on NM_001316349.2) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99752153; called by muse, mutect2
- TICAM1 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs1204402796, COSV99941123; called by muse, mutect2, varscan2
- TIMD4 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1324202892, COSV50853892, COSV99192529; called by muse, mutect2, varscan2
- TLCD3A | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100021407; called by muse, mutect2, varscan2
- TLN2 | c.4006C>T p.L1336F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.783); catalogued as COSV100169169; called by muse, mutect2, varscan2
- TLR5 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV100643294; called by muse, mutect2, varscan2
- TMEM205 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1298389351, COSV55791660; called by muse, mutect2, varscan2
- TMEM217 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs267601006, COSV60825401; called by muse, mutect2, varscan2
- TMEM50A | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100975935; called by muse, mutect2, varscan2
- TMPRSS15 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99518101; called by muse, mutect2, varscan2
- TNRC6A | c.3791A>T p.Q1264L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.534); catalogued as COSV100170097, COSV59367556; called by muse, mutect2, varscan2
- TOGARAM2 | c.3038C>T p.S1013L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); catalogued as COSV101091164; called by muse, mutect2, varscan2
- TONSL | c.2143C>T p.H715Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1187606627, COSV101340258; called by muse, mutect2, varscan2
- TOP1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV100793840; called by muse, mutect2, varscan2
- TREML1 | c.570G>A p.G190= | Splice Region (SNP) | VAF 4/19 reads (21%) | catalogued as rs1342592727, COSV100914284; called by muse, mutect2, varscan2
- TRIM36 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56693964; called by muse, mutect2, varscan2
- TRIM39 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV100935774; called by muse, mutect2, varscan2
- TRIM46 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.519); catalogued as rs1252428916, COSV100104431, COSV58112034; called by muse, mutect2, varscan2
- TRIM72 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs1317028548, COSV59069745; called by muse, mutect2, varscan2
- TRPV1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs1264614966, COSV51519697; called by muse, mutect2
- TRRAP | c.2990C>T p.T997I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1202573276, COSV100722563; called by muse, mutect2, varscan2
- TTBK1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV52494673; called by muse, mutect2, varscan2
- TTBK2 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs748766632, COSV51157748; called by muse, mutect2, varscan2
- TTC21B | c.2935T>A p.L979I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV99692417; called by muse, mutect2, varscan2
- TTC29 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100283906; called by muse, mutect2, varscan2
- TTC31 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99282210; called by muse, mutect2
- TTLL12 | c.1627C>A p.P543T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV99333521; called by muse, mutect2, varscan2
- TTLL13P | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs777598016, COSV60039247; called by muse, mutect2, varscan2
- TTN | c.70946C>T p.P23649L (on ENST00000591111; = p.P16225L on NM_003319.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV100616076; called by muse, mutect2, varscan2
- TTN | c.16781A>T p.N5594I (on ENST00000591111; = p.N4667I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/194 reads (27%) | PolyPhen possibly damaging (0.483); catalogued as COSV100616078; called by muse, mutect2, varscan2
- TTN | c.10535C>T p.A3512V (on ENST00000591111; = p.A3466V on NM_003319.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs778583163, COSV100616079; called by muse, mutect2, varscan2
- TTN | c.9736C>T p.Q3246* (on ENST00000591111; = p.Q3200* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100616082; called by muse, mutect2, varscan2
- TTN | c.5026G>A p.E1676K (on ENST00000591111; = p.E1630K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | PolyPhen probably damaging (0.994); catalogued as COSV100616086; called by muse, mutect2, varscan2
- TUBB8 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100226071; called by muse, mutect2, varscan2
- TYRO3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs924055339, COSV99777688; called by muse, mutect2, varscan2
- TYRO3 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV99777689; called by muse, mutect2, varscan2
- UBR1 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99317319; called by muse, mutect2, varscan2
- UGGT2 | c.4288C>A p.L1430I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948723; called by muse, mutect2, varscan2
- UGT2A1 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303874765, COSV54142060; called by muse, mutect2, varscan2
- UGT2A3 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as rs267600216, COSV52359885, COSV52360393; called by muse, mutect2, varscan2
- UGT2B11 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV71423525; called by muse, mutect2, varscan2
- UGT3A2 | c.948G>T p.M316I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.336); catalogued as rs772091135, COSV99236430; called by muse, mutect2, varscan2
- ULK2 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763078178, COSV100860847; called by muse, mutect2, varscan2
- UNC13C | c.2905C>T p.R969C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs191961732; called by muse, mutect2, varscan2
- UNC79 | c.1744G>A p.E582K (on ENST00000393151 / NM_001346218.2; = p.E405K on NM_020818.5) | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99828168; called by muse, mutect2, varscan2
- USH2A | c.12149G>A p.G4050E | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867523397, COSV100236038, COSV56413487, COSV56419342; called by muse, mutect2, varscan2
- USH2A | c.6961G>A p.E2321K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs746981937, COSV100236039; called by muse, mutect2, varscan2
- USP10 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99551472; called by muse, mutect2, varscan2
- USP37 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.594); catalogued as COSV99294510; called by muse, mutect2, varscan2
- VAT1L | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100213579; called by muse, mutect2, varscan2
- VAV2 | c.2602C>T p.P868S (on ENST00000371850 / NM_001134398.2; = p.P829S on NM_003371.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762978617, COSV100573481; called by muse, mutect2, varscan2
- VCAN | c.8734G>A p.E2912K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV99426073; called by muse, mutect2, varscan2
- VWA3B | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV101417789; called by muse, mutect2
- WASF2 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.755); catalogued as COSV101420786; called by muse, mutect2, varscan2
- WBP2NL | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100173827; called by muse, mutect2, varscan2
- WDR11 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99676619; called by muse, mutect2, varscan2
- WDR64 | c.3118G>A p.G1040S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV100843803; called by muse, mutect2, varscan2
- WDR72 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs770171059, COSV100854570; called by muse, mutect2, varscan2
- XIRP2 | c.832C>T p.P278S (on ENST00000628543; = p.P453S on NM_152381.6) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV54695132; called by muse, mutect2, varscan2
- ZBED9 | c.2710G>A p.D904N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101509267; called by muse, mutect2, varscan2
- ZBTB4 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100263392; called by muse, mutect2, varscan2
- ZBTB8A | c.746T>G p.I249S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.056); catalogued as COSV100331383; called by muse, mutect2, varscan2
- ZDBF2 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs745571949, COSV65621296; called by muse, mutect2
- ZFP30 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63622862; called by muse, mutect2, varscan2
- ZFP37 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.036); catalogued as COSV100953280; called by muse, varscan2
- ZHX2 | c.1921C>T p.H641Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.966); catalogued as rs776080245, COSV100073219; called by muse, mutect2, varscan2
- ZMIZ1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100566170; called by muse, mutect2, varscan2
- ZMIZ1 | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773048249, COSV100566172, COSV57904088; called by muse, mutect2, varscan2
- ZMYM6 | c.66A>C p.K22N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100451624; called by muse, mutect2, varscan2
- ZNF208 | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1163866186, COSV68109181, COSV68111424; called by muse, mutect2, varscan2
- ZNF208 | c.1185A>T p.K395N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101237044, COSV68107110; called by muse, mutect2, varscan2
- ZNF208 | c.887A>G p.K296R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.027); catalogued as COSV101237045; called by muse, mutect2, varscan2
- ZNF25 | c.555C>G p.H185Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100224645, COSV56922851; called by muse, mutect2, varscan2
- ZNF287 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101209324, COSV101209388; called by muse, mutect2, varscan2
- ZNF446 | c.1268A>G p.H423R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100236260; called by muse, mutect2, varscan2
- ZNF480 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.206); catalogued as rs1388719499, COSV100574221; called by muse, mutect2, varscan2
- ZNF490 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61008555; called by muse, mutect2, varscan2
- ZNF512 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100820817; called by muse, mutect2, varscan2
- ZNF549 | c.209A>G p.H70R (on ENST00000376233 / NM_001199295.2; = p.H57R on NM_153263.2) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs763257601, COSV99558616; called by muse, mutect2, varscan2
- ZNF557 | c.905C>T p.S302L (on ENST00000414706 / NM_001044388.2; = p.S309L on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs201284911; called by muse, mutect2, varscan2
- ZNF560 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 25/97 reads (26%) | catalogued as COSV56867231; called by muse, mutect2, varscan2
- ZNF57 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); catalogued as COSV100182938; called by muse, mutect2, varscan2
- ZNF570 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV100356194; called by muse, mutect2, varscan2
- ZNF592 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55435956; called by muse, mutect2, varscan2
- ZNF609 | c.2051C>A p.S684Y | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV100441152; called by muse, mutect2, varscan2
- ZNF627 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1193768469, COSV63142224; called by muse, mutect2, varscan2
- ZNF646 | c.3211C>T p.R1071C | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143026772; called by muse, mutect2, varscan2
- ZNF649 | c.899C>A p.S300Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.675); catalogued as COSV100031070; called by muse, mutect2, varscan2
- ZNF775 | c.842del p.F281Sfs*16 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as COSV61614009; called by mutect2, pindel
- ZNF804B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV60827351, COSV60837421; called by muse, mutect2
- ZNF83 | c.681T>G p.H227Q | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99991404; called by muse, mutect2, varscan2
- ZNF830 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as COSV100030696; called by mutect2, varscan2
- ZNF99 | c.2447C>T p.S816F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1395315614, COSV68056244; called by muse, mutect2, varscan2
- ZP2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267604453, COSV54812388; called by muse, mutect2, varscan2
- ABCA7 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FCGBP | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- GAS2L2 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- GEMIN5 | c.1220_1221del p.W407* | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, varscan2*
- HABP2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- IGHV1-24 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV1-3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2
- IGKV1-27 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- IGLV3-32 | c.306T>A p.D102E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- KRT36 | c.990del p.N331Ifs*24 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- MEN1 | c.1311_1326del p.H438Pfs*7 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel
- PAX7 | c.190del p.H64Tfs*51 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- SLC8A1 | c.396_403del p.E132Dfs*2 | Frame Shift Del (DEL) | VAF 31/139 reads (22%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TTC25 | c.307_312dup p.F103_Y104dup | In Frame Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, pindel, varscan2
- ABCA9 | c.4332G>A p.L1444= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100383159; called by muse, mutect2, varscan2
- ABCB5 | c.135C>T p.I45= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1381749515, COSV101295941; called by muse, mutect2, varscan2
- ABCC12 | c.354C>T p.F118= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100252761; called by muse, mutect2, varscan2
- ABCC2 | c.4338C>T p.C1446= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100966555; called by muse, mutect2, varscan2
- ABCC2 | c.4339C>T p.L1447= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100966556; called by muse, mutect2, varscan2
- ABCD4 | c.1593G>A p.R531= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV53993373; called by muse, mutect2, varscan2
- ABCG1 | c.759C>T p.F253= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV59203164; called by muse, mutect2, varscan2
- AC018630.4 | c.213C>T p.P71= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs1401085734, COSV99958528; called by muse, mutect2, varscan2
- ACAP2 | c.498C>T p.F166= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV100462203; called by muse, mutect2, varscan2
- ADAMTS7 | c.171C>T p.F57= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV66309439; called by muse, mutect2
- ADCY8 | c.2550C>T p.F850= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV53923505; called by muse, mutect2, varscan2
- ADGRD1 | c.1929C>T p.F643= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs267603381, COSV99895754; called by muse, mutect2, varscan2
- AFF4 | c.2901C>T p.F967= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99535014; called by muse, mutect2, varscan2
- AGRN | c.5199C>T p.G1733= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1198068368, COSV101038903; called by muse, mutect2
- AKAP1 | c.1143C>T p.L381= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100027996; called by muse, mutect2, varscan2
- ALAS2 | c.1041C>T p.S347= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100238385, COSV58188871; called by muse, mutect2, varscan2
- ALK | c.2028C>T p.I676= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs772973901, COSV66558350; called by muse, mutect2, varscan2
- ALOXE3 | c.561G>A p.G187= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100559738, COSV59075914; called by muse, mutect2
- ANK3 | c.1635G>A p.E545= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99780302; called by muse, mutect2, varscan2
- ANKDD1A | c.273G>A p.G91= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100132694; called by muse, mutect2, varscan2
- ANKRD45 | c.114C>T p.P38= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100322527; called by muse, mutect2, varscan2
- AP4B1 | c.75T>C p.D25= | Silent (SNP) | VAF 67/273 reads (25%) | catalogued as COSV99870833; called by muse, mutect2, varscan2
- APC2 | c.606C>T p.F202= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs753350102, COSV99279519; called by muse, mutect2, varscan2
- APH1B | c.573C>T p.I191= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as rs199850122, COSV99971550; called by muse, mutect2, varscan2
- APOB | c.2718C>T p.F906= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99265945; called by muse, mutect2, varscan2
- ARHGAP44 | c.558T>G p.A186= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99310862; called by muse, mutect2
- ARPC2 | c.528C>T p.V176= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99826729; called by muse, mutect2, varscan2
- ASIC2 | c.360C>T p.N120= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100726514; called by muse, varscan2
- ATP11B | c.472T>C p.L158= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as COSV100017820, COSV100017854; called by muse, mutect2, varscan2
- ATXN3L | c.399G>A p.L133= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV101019407; called by muse, mutect2, varscan2
- B4GALNT3 | c.1023C>T p.L341= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99843108; called by muse, mutect2
- B4GALT5 | c.282C>T p.T94= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV65492767; called by muse, mutect2, varscan2
- BOC | c.2091G>A p.R697= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs954897563, COSV99848815; called by muse, mutect2, varscan2
- BOD1L1 | c.6048C>T p.V2016= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV50006889; called by muse, mutect2, varscan2
- BPIFA2 | c.660C>T p.I220= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV99487895; called by muse, mutect2, varscan2
- BPIFB4 | c.777G>A p.G259= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV64950660; called by muse, mutect2
- BRINP3 | c.1437C>G p.A479= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV100818902, COSV66533549; called by muse, mutect2, varscan2
- BSN | c.6876G>A p.G2292= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1282367926, COSV99608661; called by muse, mutect2, varscan2
- C12orf56 | c.1122C>T p.D374= (on ENST00000543942 / NM_001170633.2; = p.D214= on NM_001099676.3) | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100399506; called by muse, mutect2, varscan2
- C1GALT1C1L | c.528C>T p.L176= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as rs1156781889; called by muse, mutect2, varscan2
- C1QC | c.276C>T p.P92= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101009479; called by muse, mutect2, varscan2
- C1QL2 | c.573C>A p.T191= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1182540354, COSV99733216; called by muse, mutect2, varscan2
- C4orf17 | c.1074G>A p.R358= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99910961; called by muse, mutect2, varscan2
- C8A | c.483G>A p.Q161= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100776514; called by muse, mutect2, varscan2
- CACNA1E | c.4233C>T p.P1411= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs762675688, COSV62400743, COSV62438877; called by muse, mutect2, varscan2
- CACNG4 | c.787C>T p.L263= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100047634; called by muse, mutect2, varscan2
- CAMK2B | c.430C>T p.L144= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs780676885, COSV99323105; called by muse, mutect2, varscan2
- CAMK4 | c.255C>T p.I85= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs201866448, COSV56662707; called by muse, mutect2, varscan2
- CAMKV | c.918G>A p.K306= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV56553935, COSV99615593; called by muse, mutect2, varscan2
- CASKIN2 | c.850C>T p.L284= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100395410; called by muse, mutect2, varscan2
- CASP8 | c.454C>T p.L152= (on ENST00000432109 / NM_033355.3; = p.L184= on NM_001228.4) | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs1179006754, COSV99965396; called by muse, mutect2, varscan2
- CASR | c.1578C>T p.I526= (on ENST00000490131; = p.I603= on NM_000388.4) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1332311514, COSV56136785; called by muse, mutect2
- CBLL2 | c.492C>T p.I164= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100081624; called by muse, mutect2, varscan2
- CCDC33 | c.657G>A p.R219= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV58352668; called by muse, mutect2, varscan2
- CCDC88B | c.2709G>A p.Q903= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100105506; called by muse, mutect2, varscan2
- CD300LB | c.237G>A p.K79= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV100075452, COSV58726518; called by muse, mutect2, varscan2
- CDH23 | c.5844C>T p.F1948= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1327732062, COSV99820301; called by muse, mutect2, varscan2
- CDH6 | c.1017G>A p.K339= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV99419440; called by muse, mutect2, varscan2
- CDK15 | c.918C>T p.I306= (on ENST00000652192 / NM_001366386.2; = p.I255= on NM_139158.2) | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99643249; called by muse, mutect2, varscan2
- CEACAM5 | c.1083G>A p.Q361= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV99703954; called by muse, mutect2, varscan2
- CEP250 | c.6891G>A p.R2297= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs1304644327, COSV100698961; called by muse, mutect2, varscan2
- CFHR1 | c.627G>A p.G209= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as rs1055884587, COSV100258843, COSV57626081; called by muse, mutect2, varscan2
- CGREF1 | c.45C>T p.P15= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs746602671, COSV99565191; called by mutect2, varscan2
- CHERP | c.780C>T p.I260= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs369884233; called by muse, mutect2, varscan2
- CHODL | c.543A>G p.E181= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100166849; called by muse, mutect2, varscan2
- CHST10 | c.774C>T p.D258= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as rs375736968; called by muse, mutect2, varscan2
- CIT | c.1347G>A p.K449= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99949872; called by muse, mutect2, varscan2
- CLTC | c.1260C>T p.I420= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs1478004155, COSV99292383; called by muse, mutect2, varscan2
- CMTM2 | c.657G>A p.K219= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV99216491; called by muse, mutect2, varscan2
- CMTR1 | c.1179C>T p.S393= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1325041886, COSV100990876, COSV100990937; called by muse, mutect2, varscan2
- CNGA2 | c.1371T>C p.D457= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100323733; called by muse, mutect2, varscan2
- CNTN4 | c.2076G>A p.R692= | Silent (SNP) | VAF 36/185 reads (19%) | catalogued as COSV100639153; called by muse, mutect2, varscan2
- COCH | c.1581G>A p.R527= (on ENST00000216361 / NM_001347720.1; = p.R462= on NM_004086.3) | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV53551726, COSV99363670; called by muse, mutect2, varscan2
- COQ8B | c.1083C>T p.F361= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV54687750; called by muse, mutect2, varscan2
- CPAMD8 | c.1686C>A p.A562= (on ENST00000651564; = p.A515= on NM_015692.5) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99359449; called by muse, mutect2, varscan2
- CREBBP | c.2916C>T p.V972= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99270342; called by muse, mutect2, varscan2
- CYBRD1 | c.711A>G p.P237= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100361351; called by muse, mutect2, varscan2
- CYP2A7 | c.267G>A p.E89= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99394133; called by muse, mutect2, varscan2
- CYP3A7 | c.789G>A p.E263= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV60482341; called by muse, mutect2, varscan2
- CYYR1 | c.219C>T p.I73= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV54835604; called by muse, mutect2, varscan2
- DCX | c.507G>A p.Q169= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV57570739; called by muse, mutect2, varscan2
- DEFB131A | c.159C>T p.F53= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100607802; called by muse, mutect2, varscan2
- DENND2B | c.1146C>T p.P382= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs1430856362, COSV100567536; called by muse, mutect2, varscan2
- DHX34 | c.492C>T p.I164= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs148693538; called by muse, mutect2, varscan2
- DIP2A | c.1926G>C p.S642= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100595886; called by muse, mutect2, varscan2
- DNAH2 | c.6612C>T p.L2204= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV101209382; called by muse, mutect2, varscan2
- DNAH3 | c.3834C>T p.V1278= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99766970; called by muse, mutect2, varscan2
- DOCK3 | c.4776C>T p.V1592= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99812592; called by muse, mutect2, varscan2
- DTX3L | c.1950C>T p.N650= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99950055; called by muse, mutect2, varscan2
- DYNC1H1 | c.1017C>T p.F339= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100794987; called by muse, mutect2, varscan2
- EDARADD | c.361T>C p.L121= (on ENST00000334232 / NM_145861.4; = p.L111= on NM_080738.4) | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100512794; called by muse, mutect2
- EFCAB13 | c.2154T>C p.F718= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100516603; called by muse, mutect2, varscan2
- EMID1 | c.1311G>A p.R437= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1339034471, COSV99328556; called by muse, mutect2, varscan2
281 further variants in this file (0 protein-altering or splice-affecting, 257 silent, 24 other) are not listed here.
